Somatic mutation profile of tumor specimen TCGA-60-2716-01A (aliquot TCGA-60-2716-01A-01D-1522-08) from TCGA case TCGA-60-2716, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 39.3 years (14,345 days).
Specimen TCGA-60-2716-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 898d2040-70fc-4c52-8b6c-318d9ce9b8a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2716-11A (Solid Tissue Normal), aliquot TCGA-60-2716-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13f37576-8d41-4a58-8700-2c76319f09af

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C22orf42 | c.654+2T>C p.X218_splice | Splice Site (SNP) | VAF 85/242 reads (35%) | catalogued as COSV101173350; called by muse, mutect2, varscan2
- CTNND2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs774793947, COSV58874187; called by muse, mutect2, varscan2
- IRX2 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.77); catalogued as rs751054712, COSV100121810; called by muse, varscan2
- LMBRD2 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs759413826, COSV99683014; called by muse, mutect2, varscan2
- MYD88 | c.161T>A p.M54K | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100085639, COSV100086226; called by muse, mutect2, varscan2
- NVL | c.2013G>T p.K671N | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs149269387, COSV99894664; called by muse, mutect2, varscan2
- RRP8 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324069072, COSV99601974; called by muse, mutect2, varscan2
- SYNE1 | c.18163T>C p.S6055P (on ENST00000367255 / NM_182961.4; = p.S5984P on NM_033071.3) | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99571074; called by muse, mutect2, varscan2
- TRPM4 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV53262326, COSV99420385; called by muse, mutect2, varscan2
- WDR35 | c.1334C>T p.S445L (on ENST00000345530 / NM_001006657.2; = p.S434L on NM_020779.4) | Missense Mutation (SNP) | VAF 129/312 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs368497711; called by muse, mutect2, varscan2
- ZFHX4 | c.1166C>A p.S389* | Nonsense Mutation (SNP) | VAF 28/72 reads (39%) | catalogued as COSV99262910, COSV99264559; called by muse, mutect2, varscan2
- ZNF609 | c.554T>G p.V185G | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.085); catalogued as rs764206103, COSV100441395; called by muse, mutect2
- TP53I11 | c.453_456del p.A152Rfs*95 | Frame Shift Del (DEL) | VAF 86/239 reads (36%) | called by mutect2, pindel, varscan2
- KANK3 | c.1419C>T p.L473= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100445068; called by muse, mutect2, varscan2
- OR56A1 | c.708G>A p.A236= | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as rs780178315, COSV100360509; called by muse, mutect2, varscan2
- SIL1 | c.723C>T p.L241= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs765291894, COSV54533472, COSV99498285; called by muse, mutect2, varscan2
- TTN | c.36645C>T p.N12215= (on ENST00000591111; = p.N4791= on NM_003319.4) | Silent (SNP) | VAF 88/240 reads (37%) | catalogued as rs559906667, COSV100601664; ClinVar: likely benign; called by muse, mutect2, varscan2
